FM case AD17727 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/d85c246f-ad0a-4cc9-bcd4-fb710fee3652

Female, 51.2 years: Carcinosarcoma, NOS (ICD-O-3 8980/3) of the lung; primary biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
